Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A852, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A852-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Surgical Pathology:

(note)

Name .

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

CERVIX, BIOPSY:

- INVASIVE SQUAMOUS CELL CARCINOMA
- SEE COMMENT

ICD.O-3
Carcinoma, squamous cell NOS 8070/3
Site Cervix NOS C53.9
9/27/14

Staff Pathologist

Comment

No lymphovascular space invasion identified.

Pertinent Clinical Information

A -year-old with cervical cancer.

Gross Description

Specimen Material: Cervical biopsy.

The case is received in one part labeled with the patient's name
medical record number and given accession number , and it
is accompanied by a requisition form labeled with the same name and
accession number.

Received in formalin labeled "CERVICAL BIOPSY," is a 0.8 cm in greatest
dimension tan rubbery ovoid tissue. The specimen is submitted in toto
following filtration in cassette A.

Pathology Assistant

Microscopic Description

Performed

The staff pathologist listed below has reviewed this case.

Electronically Signed Out

Staff Pathologist

[page 2 of 3]
Result History

... SURGICAL PATHOLOGY (Order .

- Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date

Order Time

Result Information

Result Date and Time

Status
Final resultPriority
Routine**Received Date/Time**

Received Date

Received Time

Order Providers

Authorizing Provider

Encounter Provider
None**Encounter**[View Encounter](#)**Order****SURGICAL PATHOLOGY****(Order****Administration Details**No Administrations
Recorded**Order Information**

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Order DetailsFrequency
ONCEDuration
1 occurrencePriority
RoutineOrder Class
Normal**Quantity**Ordering Quantity
1**Original Order**

Ordered On

Ordered By

Transfer Service**Collection Information**

Collection Date

Collection Time

Resulting Agency

Provider Information

Ordering User

Ordering Provider

Authorizing Provider

Attending Provider(s)

Admitting Provider

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)

[page 3 of 3]
Orders Needing Specimen Collection

**** None ****

Source: NCI Genomic Data Commons file f626f7ee-0074-441c-8b24-7bfcc2a2664b (TCGA-JW-A852.7333C03D-0CDA-4BDE-A213-6FD7D3ACB382.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).